Surgical pathology report (de-identified scan), TCGA case TCGA-B0-4842, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-B0-4842-01A (Primary Tumor).

FINAL DIAGNOSIS:**PART 1:****RIGHT KIDNEY, LAPAROSCOPIC RADICAL NEPHRECTOMY -**

- A. RENAL CELL CARCINOMA, CONVENTIONAL (CLEAR CELL) TYPE, PREDOMINANT FUHRMAN'S NUCLEAR GRADE 3 OF 4, WITH FOCAL FUHRMAN NUCLEAR GRADE 4 OF 4 (slide 1L). FOCAL HEMORRHAGE AND RARE NECROSIS ARE IDENTIFIED.
- B. CARCINOMA INVADERS INTO THE PERINEPHRIC ADIPOSE TISSUE, FOCALLY INFILTRATES GEROTA'S FASCIA AND IS PRESENT AT THE CORRESPONDING PERINEPHRIC SOFT TISSUE MARGIN IN THE REGION OF THE UPPER POLE OF THE KIDNEY (slide 1F); THE LINEAR EXTENT OF THE POSITIVE MARGIN ON THE NEPHRECTOMY SPECIMEN IS 0.15 CM (see comment).
- C. SMALL, NON-OCCLUSIVE, NON-ADHERENT, GROSSLY-INAPPARENT TUMOR FRAGMENT WITH ASSOCIATED FIBRIN IS IDENTIFIED IN THE LUMEN OF THE RENAL ARTERY AT THE RENAL ARTERY RESECTION MARGIN (see comment).
- D. TUMOR THROMBOEMBOLUS IS PRESENT WITHIN A SMALL THIN-WALLED VESSEL WITHIN THE TUMOR.
- E. BENIGN PROXIMAL URETER AND MAIN RENAL VEIN.
- F. NON-NEOPLASTIC RENAL PARENCHYMA CONTAINS A BENIGN SIMPLE CORTICAL CYST (slide 1N), AND IS OTHERWISE UNREMARKABLE.
- G. PATHOLOGIC TNM STAGE: pT3a+ Nx Mx.

PART 2:**RIGHT ADRENAL GLAND, RESECTION -**

BENIGN ADRENAL GLAND AND ADIPOSE TISSUE WITH NO SIGNIFICANT PATHOLOGIC CHANGES THUS FAR (see comment).

COMMENT:

Parts 1 and 2: This renal tumor is very large with gross invasion into the perinephric adipose tissue, and with the Gerota's fascia stretched over the tumor. A 0.15 cm defect is present in a section containing apparent Gerota's fascia in the upper pole region, with carcinoma present at the corresponding inked margin (slide 1F). It is not certain whether or not the tumor has invaded through Gerota's fascia into surrounding soft tissue, or whether this represents a small surgical defect in Gerota's fascia; therefore, the assigned pT stage is pT3a+. The case was discussed with [REDACTED] who indicated that he noted a small defect in the this area of the specimen during intraoperative examination, and thought there was a small amount of residual tumor in the corresponding adjacent tissue near the adrenal gland. He then resected the adrenal gland and surrounding soft tissue. No tumor was recognized grossly in the adrenal specimen (part 2) during pathologic examination and sectioning; the remaining tissue in part 2 will be submitted for histology, with the result to follow in an addendum. It is most likely that the final margin in the soft tissue adjacent to the upper pole of the kidney is benign.

The small tumor fragment in the main renal artery lumen (section 1A) was not identified grossly, and is not attached to the wall of the artery. However, the tumor cells are surrounded by fibrin. It is not certain whether this represents a tumor thromboembolus or an artifactually displaced tumor fragment occurring during sectioning. The renal artery wall margin appears to be free of tumor.

GROSS DESCRIPTION:

The specimen is received in two parts.

Part 1 is received fresh, properly labeled and identified with the patient's name [REDACTED] as "right kidney". The specimen consists of a kidney surrounded by adipose tissue. On external examination the Gerota's fascia is stretched and smooth. On sectioning the kidney, a 12.5 cm in greatest dimension tumor is identified at one of the poles. The tumor involves both the cortex and the medulla, compresses the renal pelvis and extends into the perinephric and hilar adipose tissue. On serial sectioning, most of the tumor is homogeneously beige and soft. Yellow foci and areas of hemorrhage and necrosis are also identified. The non-neoplastic renal parenchyma shows a 5 cm in greatest dimension slightly irregular cortical cyst with smooth wall and no evidence of tumor at the opposite pole from the tumor. The remaining non-neoplastic renal parenchyma is grossly unremarkable.

Source: NCI Genomic Data Commons file 4f7c1be9-e935-4438-86af-5476ff73b354 (TCGA-B0-4842.A1922EF5-4161-4ABA-91AE-C4ADE5A863D6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).